Somatic mutation profile of tumor specimen TCGA-EL-A3CZ-01A (aliquot TCGA-EL-A3CZ-01A-11D-A19J-08) from TCGA case TCGA-EL-A3CZ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 37.6 years (13,718 days).
Specimen TCGA-EL-A3CZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f4268e9-1bdb-46fd-8b14-9bb33744b7a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3CZ-10A (Blood Derived Normal), aliquot TCGA-EL-A3CZ-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28da7fe3-dc2d-4653-80c5-6c9ead1d8630

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 35/84 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GNPAT | c.1973C>T p.A658V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as COSV64153923; called by muse, mutect2
- GPATCH8 | c.4430C>G p.T1477S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0.049); catalogued as COSV59196383; called by muse, mutect2, varscan2
- PHIP | c.2095C>T p.R699W | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV51507676; called by muse, mutect2, varscan2
- RAPH1 | c.3092dup p.N1031Kfs*42 | Frame Shift Ins (INS) | VAF 33/98 reads (34%) | catalogued as rs1383681040; called by mutect2, pindel, varscan2
- BTRC | c.1005C>T p.C335= (on ENST00000370187 / NM_033637.4; = p.C299= on NM_003939.5) | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as COSV64580254; called by muse, mutect2
